Somatic mutation profile of tumor specimen 0DVVLC from CCDI case PBCLEA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 3.8 years (1,403 days).
Specimen 0DVVLC: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94944518-5cbc-40e1-9fc6-e0bf0232b90b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVVMA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30471420-617f-4587-b107-6e3966afd76e

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFIP1 | c.1015G>A p.A339T (on ENST00000353617 / NM_001287432.1; = p.A307T on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/425 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754778801; called by muse, mutect2
- IFNGR1 | c.1414G>A p.G472S | Missense Mutation (SNP) | VAF 155/373 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs55924399; called by muse, mutect2, varscan2
- NF2 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 112/135 reads (83%) | catalogued as CD004510; called by muse, mutect2, varscan2
- PTPRN | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 101/257 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs756735224, COSV55348618; called by muse, mutect2, varscan2
- IQCA1L | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- KANK2 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.149); called by muse, mutect2
- PCDHGA1 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 313/746 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- C2CD3 | c.325+33C>T | Intron (SNP) | VAF 52/111 reads (47%) | catalogued as rs771004395, COSV58097718; called by muse, mutect2, varscan2
- MARK1 | c.1276+45C>A | Intron (SNP) | VAF 10/162 reads (6%) | catalogued as rs1452161376; called by muse, mutect2
